Somatic mutation profile of cancer-model specimen HCM-BROD-0472-C34-85M (3D Organoid, passage 10; aliquot HCM-BROD-0472-C34-85M-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0472-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 65.9 years (24,082 days).
Specimen HCM-BROD-0472-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec607457-de56-4dc3-bae0-7dffb0fb15ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0472-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0472-C34-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9144c79b-549c-4f0a-a571-56b11d83b2cc

The open-access MAF lists 531 somatic variants for this specimen: 377 protein-altering or splice-affecting, 131 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 326, Silent 131, Nonsense Mutation 26, Frame Shift Del 15, Intron 13, Splice Site 5, 5'Flank 4, 5'UTR 4, In Frame Del 3, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 184/184 reads (100%) | catalogued as rs121913304, CM942039, COSV57296489; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 202/203 reads (100%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs780077643, COSV56853758; called by muse, mutect2, varscan2
- AC136428.1 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 203/306 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); catalogued as rs1261897585; called by muse, mutect2, varscan2
- ACTN3 | c.2043G>C p.Q681H | Missense Mutation (SNP) | VAF 150/526 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV59747326; called by muse, mutect2, varscan2
- ADCY8 | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); catalogued as rs566810608; called by muse, mutect2, varscan2
- ALPK2 | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 339/339 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs573563411, COSV100863938; called by muse, mutect2, varscan2
- ANK2 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 256/359 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99053417; called by muse, mutect2, varscan2
- APOBEC4 | c.545C>A p.P182Q | Missense Mutation (SNP) | VAF 343/493 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58017650; called by muse, mutect2, varscan2
- ATXN2 | c.2837C>T p.P946L (on ENST00000550104; = p.P786L on NM_002973.4) | Missense Mutation (SNP) | VAF 292/292 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66483733; called by muse, mutect2, varscan2
- BOC | c.1100A>T p.Q367L | Missense Mutation (SNP) | VAF 191/589 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as rs779844168; called by muse, mutect2, varscan2
- BSG | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs1372990640; called by muse, mutect2, varscan2
- CCDC38 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 251/252 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100717650; called by muse, mutect2, varscan2
- CCDC87 | c.1613C>A p.P538H | Missense Mutation (SNP) | VAF 350/532 reads (66%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs538810937; called by muse, mutect2, varscan2
- CCT7 | c.1104G>C p.K368N | Missense Mutation (SNP) | VAF 247/493 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); catalogued as COSV99241020; called by muse, mutect2, varscan2
- CEP112 | c.690+1G>A p.X230_splice | Splice Site (SNP) | VAF 141/323 reads (44%) | catalogued as rs1203415267; called by muse, mutect2, varscan2
- CGAS | c.1268G>C p.R423T | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100943649; called by muse, mutect2, varscan2
- CMYA5 | c.9017G>T p.S3006I | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV71404624; called by muse, mutect2, varscan2
- COL1A2 | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51960509, COSV51967824; called by muse, mutect2, varscan2
- CRB1 | c.2371G>T p.G791* | Nonsense Mutation (SNP) | VAF 219/219 reads (100%) | catalogued as CM155782, COSV66333514; called by muse, mutect2, varscan2
- DERL3 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 399/608 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs747617476; called by muse, mutect2, varscan2
- DHFR2 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 91/556 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775609912, COSV58936660; called by muse, mutect2, varscan2
- DIPK1C | c.1011C>A p.C337* | Nonsense Mutation (SNP) | VAF 154/154 reads (100%) | catalogued as COSV59725360; called by muse, mutect2, varscan2
- DNAH5 | c.12080G>T p.G4027V | Missense Mutation (SNP) | VAF 329/546 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV54249439; called by muse, mutect2, varscan2
- DOCK10 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 239/398 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.393); catalogued as COSV51373283; called by muse, mutect2, varscan2
- DOP1B | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 66/330 reads (20%) | catalogued as rs1569025509; called by mutect2, varscan2
- DYNC2H1 | c.6886G>T p.G2296C | Missense Mutation (SNP) | VAF 96/137 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62085984; called by muse, mutect2, varscan2
- EBF3 | c.1574G>A p.S525N | Missense Mutation (SNP) | VAF 335/335 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as rs982052126, COSV62472198; called by muse, mutect2, varscan2
- EIPR1 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 182/727 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775391718; called by muse, mutect2, varscan2
- ELMOD1 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 237/353 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs373004553; called by muse, mutect2, varscan2
- EML3 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 323/532 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV53884325; called by muse, mutect2, varscan2
- ERICH1 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs763310568; called by muse, mutect2, varscan2
- ERICH3 | c.4250C>A p.A1417E | Missense Mutation (SNP) | VAF 297/297 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV100443269; called by muse, mutect2, varscan2
- ETS2 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as rs762726949; called by muse, mutect2, varscan2
- EVPL | c.4355G>A p.R1452Q | Missense Mutation (SNP) | VAF 207/926 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as rs1413866393; called by muse, mutect2, varscan2
- FAM86B1 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 187/397 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.076); catalogued as rs1343747997; called by muse, mutect2, varscan2
- FOXI3 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 138/704 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1427389100, COSV67916788; called by muse, mutect2, varscan2
- FOXP1 | c.1537G>A p.V513M | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1300281537; called by muse, mutect2, varscan2
- FUT3 | c.1035G>C p.Q345H | Missense Mutation (SNP) | VAF 588/588 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.29); catalogued as COSV54607140; called by muse, mutect2, varscan2
- GAS7 | c.725G>T p.R242L (on ENST00000432992 / NM_201433.2; = p.R102L on NM_003644.3) | Missense Mutation (SNP) | VAF 194/194 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV100097042; called by muse, mutect2, varscan2
- GOLGA6L2 | c.30C>A p.H10Q | Missense Mutation (SNP) | VAF 76/242 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.194); catalogued as rs765308989; called by muse, mutect2, varscan2
- GPR176 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 186/547 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.551); catalogued as COSV54446062; called by muse, mutect2, varscan2
- GPR32 | c.480G>A p.W160* | Nonsense Mutation (SNP) | VAF 199/630 reads (32%) | catalogued as rs764470671; called by muse, mutect2, varscan2
- GRIK4 | c.2476G>T p.E826* | Nonsense Mutation (SNP) | VAF 197/345 reads (57%) | catalogued as COSV70804710; called by muse, mutect2, varscan2
- H2AC14 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100297676; called by muse, mutect2, varscan2
- HEPH | c.3469A>G p.K1157E (on ENST00000343002; = p.K890E on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 229/230 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs760416369; called by muse, mutect2, varscan2
- IFIT3 | c.1186del p.E396Kfs*28 | Frame Shift Del (DEL) | VAF 98/255 reads (38%) | catalogued as COSV99260297; called by mutect2, pindel, varscan2
- IPO11 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs1372760104; called by muse, mutect2, varscan2
- ISLR2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 217/655 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs1304784130, COSV62304266; called by muse, varscan2
- ISOC2 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 327/453 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs967027571; called by muse, mutect2, varscan2
- ITGA1 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 152/309 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200169693; called by muse, mutect2
- ITPR3 | c.2574G>T p.K858N | Missense Mutation (SNP) | VAF 95/383 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV65407404; called by muse, mutect2, varscan2
- ITPRID2 | c.2318A>G p.Y773C | Missense Mutation (SNP) | VAF 109/384 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs200766900; called by muse, mutect2, varscan2
- KCNA5 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 310/736 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52908892; called by muse, varscan2
- KCNK12 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 357/685 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs1234511570, COSV100009838; called by muse, mutect2, varscan2
- KIAA1217 | c.3848G>T p.G1283V | Missense Mutation (SNP) | VAF 110/228 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs1320330860; called by muse, mutect2, varscan2
- LAMA1 | c.6703G>T p.G2235W | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67544000; called by mutect2, varscan2
- LCE3A | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 149/716 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.347); catalogued as rs763302367; called by muse, mutect2, varscan2
- LDAH | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 262/481 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.209); catalogued as rs763001302; called by muse, mutect2, varscan2
- LRP1B | c.8961del p.T2988Lfs*30 | Frame Shift Del (DEL) | VAF 96/413 reads (23%) | catalogued as COSV67245074; called by mutect2, pindel, varscan2
- MAGEE1 | c.1762C>G p.L588V | Missense Mutation (SNP) | VAF 217/433 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63912154; called by muse, mutect2, varscan2
- MAGEE2 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 162/330 reads (49%) | catalogued as rs746202577, COSV64897231; called by muse, mutect2, varscan2
- MAGEL2 | c.3377G>A p.C1126Y | Missense Mutation (SNP) | VAF 264/436 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.112); catalogued as COSV58567314; called by muse, mutect2, varscan2
- MCTP1 | c.145C>A p.R49S | Missense Mutation (SNP) | VAF 501/734 reads (68%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs766747520; called by muse, mutect2, varscan2
- MEF2C | c.916C>G p.Q306E | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100424967; called by muse, mutect2, varscan2
- MPST | c.116C>T p.P39L (on ENST00000341116 / NM_001369904.2; = p.P59L on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/732 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1011808569; called by muse, mutect2, varscan2
- MROH5 | c.3544G>T p.V1182F | Missense Mutation (SNP) | VAF 42/496 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1448025769; called by muse, mutect2
- MYH11 | c.5528C>A p.S1843* | Nonsense Mutation (SNP) | VAF 145/503 reads (29%) | catalogued as COSV55556983; called by muse, mutect2, varscan2
- MYO5B | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 107/211 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53218957; called by muse, mutect2, varscan2
- NCAM1 | c.2563G>A p.E855K (on ENST00000316851 / NM_181351.5; = p.E845K on NM_000615.7) | Missense Mutation (SNP) | VAF 217/354 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs369107930; called by muse, mutect2, varscan2
- NELL1 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1199157497, COSV54290404, COSV54327653; called by muse, mutect2, varscan2
- NIBAN3 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 202/202 reads (100%) | catalogued as rs780450113; called by muse, mutect2, varscan2
- NRP1 | c.2696A>G p.Y899C | Missense Mutation (SNP) | VAF 288/288 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769226149; called by muse, mutect2, varscan2
- NTN5 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 527/792 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); catalogued as rs746645117; called by muse, mutect2, varscan2
- OR2T8 | c.16T>C p.Y6H | Missense Mutation (SNP) | VAF 123/336 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100178370; called by muse, mutect2, varscan2
- OR52L1 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.576); catalogued as COSV59989749; called by muse, mutect2, varscan2
- OR5A2 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 188/308 reads (61%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as COSV57391985; called by muse, mutect2, varscan2
- OR5D18 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 269/415 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV61736239; called by muse, mutect2, varscan2
- OR5K3 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.162); catalogued as COSV67350725; called by muse, mutect2, varscan2
- OSMR | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 183/463 reads (40%) | catalogued as COSV57083546; called by muse, mutect2, varscan2
- OTOGL | c.4870G>A p.D1624N (on ENST00000547103; = p.D1615N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/115 reads (100%) | SIFT tolerated (0.93); PolyPhen benign (0.02); catalogued as COSV54013456; called by muse, mutect2, varscan2
- PAQR9 | c.1019C>A p.P340Q | Missense Mutation (SNP) | VAF 303/552 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs992045390; called by muse, mutect2, varscan2
- PCDH19 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 476/477 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867012022, COSV55259918; called by muse, mutect2, varscan2
- PCDHB12 | c.1466del p.S489Cfs*53 | Frame Shift Del (DEL) | VAF 295/933 reads (32%) | catalogued as COSV53397614; called by mutect2, pindel, varscan2
- PCDHB6 | c.1999C>A p.P667T | Missense Mutation (SNP) | VAF 581/883 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as rs546885437; called by muse, mutect2, varscan2
- PCDHB7 | c.1713del p.C572Afs*15 | Frame Shift Del (DEL) | VAF 269/1039 reads (26%) | catalogued as COSV99176949; called by mutect2, pindel, varscan2
- PEAR1 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 507/922 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747412963; called by muse, mutect2, varscan2
- PID1 | c.506G>A p.C169Y (on ENST00000354069 / NM_001330156.1; = p.C167Y on NM_017933.5) | Missense Mutation (SNP) | VAF 141/448 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766796821; called by muse, mutect2, varscan2
- PKD1 | c.3184C>T p.Q1062* | Nonsense Mutation (SNP) | VAF 110/400 reads (28%) | catalogued as CM1210862; called by muse, varscan2
- PKHD1 | c.6676A>G p.M2226V | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs751398880; called by muse, mutect2, varscan2
- PKHD1 | c.5879C>A p.T1960K | Missense Mutation (SNP) | VAF 204/320 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs534831346; called by muse, mutect2, varscan2
- PPIP5K1 | c.3550A>T p.T1184S (on ENST00000396923; = p.T1159S on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/390 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs1460001095; called by muse, mutect2, varscan2
- PREP | c.149C>A p.P50H (on ENST00000369110; = p.P116H on NM_002726.5) | Missense Mutation (SNP) | VAF 184/293 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100963817; called by muse, mutect2, varscan2
- PRKAG2 | c.1236G>T p.M412I | Missense Mutation (SNP) | VAF 132/214 reads (62%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99835439; called by muse, mutect2, varscan2
- PRM2 | c.164del p.R55Pfs*72 | Frame Shift Del (DEL) | VAF 236/814 reads (29%) | catalogued as COSV54113501; called by mutect2, pindel, varscan2
- PSG11 | c.993C>G p.F331L | Missense Mutation (SNP) | VAF 278/422 reads (66%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1178481939; called by muse, mutect2, varscan2
- PTPRO | c.1015T>A p.S339T | Missense Mutation (SNP) | VAF 114/535 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.024); catalogued as rs375448871; called by muse, mutect2, varscan2
- RFPL4B | c.84C>A p.H28Q | Missense Mutation (SNP) | VAF 117/305 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773462376; called by muse, mutect2, varscan2
- RFX7 | c.347A>G p.N116S (on ENST00000559447 / NM_001368074.1; = p.N213S on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 202/316 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1489534308; called by muse, mutect2, varscan2
- RGS6 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 260/503 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59586409; called by muse, mutect2, varscan2
- RIBC1 | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 325/325 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV51448170; called by muse, mutect2, varscan2
- RP1L1 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 183/184 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66756179, COSV66759892; called by muse, mutect2, varscan2
- RUNDC3B | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 156/258 reads (60%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV99714828; called by muse, mutect2, varscan2
- RYR3 | c.10525C>T p.H3509Y (on ENST00000389232; = p.H3510Y on NM_001036.6) | Missense Mutation (SNP) | VAF 120/185 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs767621712, COSV66790427; called by muse, mutect2, varscan2
- SDSL | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 285/286 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs751307425; called by muse, mutect2, varscan2
- SETX | c.1682A>T p.K561M | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99809434; called by muse, mutect2, varscan2
- SIRT2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 131/474 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs926292218, COSV50874936; called by muse, mutect2, varscan2
- SLC19A1 | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 194/1021 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV60753833; called by muse, mutect2, varscan2
- SNAPC4 | c.2175G>C p.Q725H | Missense Mutation (SNP) | VAF 271/555 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.459); catalogued as rs201265450; called by muse, mutect2, varscan2
- SSH2 | c.3216C>A p.H1072Q | Missense Mutation (SNP) | VAF 296/297 reads (100%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.024); catalogued as COSV52175653; called by muse, mutect2, varscan2
- SSTR1 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 544/902 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV57455597; called by muse, varscan2
- TANGO2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 268/414 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100530030; called by muse, mutect2, varscan2
- TBX15 | c.562G>T p.A188S (on ENST00000369429 / NM_001330677.2; = p.A82S on NM_152380.3) | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99254281; called by muse, mutect2, varscan2
- TENM2 | c.3268T>C p.S1090P (on ENST00000518659 / NM_001122679.2; = p.S858P on NM_001080428.3) | Missense Mutation (SNP) | VAF 160/513 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.391); catalogued as rs367950355; called by muse, mutect2, varscan2
- TERF1 | c.1178C>G p.S393C (on ENST00000276603 / NM_017489.3; = p.S373C on NM_003218.4) | Missense Mutation (SNP) | VAF 177/268 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1257013963; called by muse, mutect2, varscan2
- TGM1 | c.1936G>T p.V646L | Missense Mutation (SNP) | VAF 216/587 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as rs765539126; called by muse, mutect2, varscan2
- TRIML1 | c.556C>A p.H186N | Missense Mutation (SNP) | VAF 92/602 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV100205689; called by muse, mutect2
- TRPM4 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 52/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53260289; called by muse, mutect2, varscan2
- TTN | c.10595C>T p.P3532L (on ENST00000591111; = p.P3486L on NM_003319.4) | Missense Mutation (SNP) | VAF 134/384 reads (35%) | catalogued as rs727503662; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- TULP1 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 159/471 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100003869; called by muse, mutect2, varscan2
- UPK3BL1 | c.615C>G p.I205M | Missense Mutation (SNP) | VAF 68/374 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100330866; called by muse, varscan2
- USP12 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); catalogued as COSV56658490; called by muse, mutect2, varscan2
- ZAN | c.6583G>A p.G2195R | Missense Mutation (SNP) | VAF 137/437 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1347976699; called by muse, mutect2, varscan2
- ZNF454 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 138/463 reads (30%) | catalogued as rs1217144684, COSV100194890; called by muse, mutect2, varscan2
- ZNF501 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 109/253 reads (43%) | catalogued as rs758058321; called by muse, mutect2, varscan2
- ZNF790 | c.224G>A p.C75Y | Missense Mutation (SNP) | VAF 166/398 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1285339090; called by muse, mutect2, varscan2
- ABCA13 | c.1318G>C p.A440P | Missense Mutation (SNP) | VAF 219/330 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- ABCA3 | c.1843G>C p.D615H | Missense Mutation (SNP) | VAF 135/432 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCD2 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 297/581 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACACB | c.3306G>C p.E1102D | Missense Mutation (SNP) | VAF 117/262 reads (45%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM2A | c.1698G>T p.K566N (on ENST00000219054; = p.K487N on NM_001308169.2) | Missense Mutation (SNP) | VAF 85/370 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ACSM2A | c.1699G>T p.E567* (on ENST00000219054; = p.E488* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 83/368 reads (23%) | called by muse, mutect2, varscan2
- ACTC1 | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 243/393 reads (62%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ACY3 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 258/398 reads (65%) | SIFT tolerated (0.25); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ADAM20 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 259/763 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ADAMTS7 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 225/697 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAMTS9 | c.3348G>T p.W1116C | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHCY | c.914A>G p.E305G | Missense Mutation (SNP) | VAF 310/1080 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AIM2 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 262/643 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AL162417.1 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 266/541 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALK | c.3794T>A p.V1265E | Missense Mutation (SNP) | VAF 258/519 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ANK2 | c.9C>G p.N3K | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ANKFN1 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANKFN1 | c.1748C>A p.P583Q | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AP2A2 | c.1731G>C p.Q577H | Missense Mutation (SNP) | VAF 511/511 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF1 | c.2413G>T p.A805S | Missense Mutation (SNP) | VAF 150/226 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP30 | c.1687-1G>A p.X563_splice | Splice Site (SNP) | VAF 221/1115 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.461C>A p.T154N | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ARID1A | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 869/871 reads (100%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ASB1 | c.38del p.P13Rfs*8 | Frame Shift Del (DEL) | VAF 151/635 reads (24%) | called by mutect2, pindel, varscan2
- ASB6 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 219/221 reads (99%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATM | c.6876G>C p.Q2292H | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATN1 | c.1352_1359del p.L451Qfs*70 | Frame Shift Del (DEL) | VAF 166/835 reads (20%) | called by mutect2, pindel, varscan2
- BDP1 | c.4768_4784del p.Q1590* | Frame Shift Del (DEL) | VAF 119/317 reads (38%) | called by mutect2, pindel, varscan2
- BIRC6 | c.2724G>T p.Q908H | Missense Mutation (SNP) | VAF 195/455 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BSG | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 192/193 reads (99%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTN1A1 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 143/484 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C10orf105 | c.234C>A p.H78Q | Missense Mutation (SNP) | VAF 507/509 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- C19orf81 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 337/467 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C20orf203 | c.570del p.S191Rfs*117 | Frame Shift Del (DEL) | VAF 71/597 reads (12%) | called by mutect2, pindel, varscan2
- C20orf96 | c.262A>C p.K88Q (on ENST00000360321 / NM_153269.3; = p.K87Q on NM_080571.1) | Missense Mutation (SNP) | VAF 184/568 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C4orf47 | c.899A>T p.N300I | Missense Mutation (SNP) | VAF 65/541 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CACNA1S | c.1835C>A p.T612K | Missense Mutation (SNP) | VAF 106/345 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D4 | c.1108G>C p.V370L | Missense Mutation (SNP) | VAF 344/661 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CACNG3 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 290/454 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- CAD | c.1713G>T p.R571S | Missense Mutation (SNP) | VAF 373/738 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBFB | c.177_179delinsAT p.T60* | Frame Shift Del (DEL) | VAF 139/315 reads (44%) | called by pindel, varscan2*
- CD1B | c.395T>A p.L132Q | Missense Mutation (SNP) | VAF 431/828 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- CD47 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CD8A | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 305/656 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- CDH12 | c.1737G>C p.Q579H | Missense Mutation (SNP) | VAF 152/816 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CDHR2 | c.3374A>T p.D1125V | Missense Mutation (SNP) | VAF 127/452 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- CDK5R2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 177/526 reads (34%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- CFAP61 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 160/342 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHAT | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD7 | c.1405A>T p.R469W | Missense Mutation (SNP) | VAF 115/345 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHSY3 | c.1829C>A p.A610D | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2
- CLCA4 | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 25/353 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2
- CNGA3 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 412/832 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CNTNAP5 | c.2090C>G p.T697S | Missense Mutation (SNP) | VAF 155/230 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- COL20A1 | c.3383T>C p.V1128A | Missense Mutation (SNP) | VAF 393/741 reads (53%) | SIFT tolerated (0.91); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COL6A5 | c.2663G>T p.G888V | Missense Mutation (SNP) | VAF 247/481 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL6A5 | c.5066G>C p.G1689A | Missense Mutation (SNP) | VAF 172/399 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACD | c.1534_1536del p.A512del | In Frame Del (DEL) | VAF 146/478 reads (31%) | called by pindel, varscan2
- DACT3 | c.892_896del p.S298Afs*52 | Frame Shift Del (DEL) | VAF 98/410 reads (24%) | called by mutect2, pindel, varscan2
- DCTN1 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 249/581 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DDX27 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 112/493 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEFB104A | c.163T>A p.Y55N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.134); called by mutect2, varscan2
- DIP2B | c.2369del p.P790Hfs*11 | Frame Shift Del (DEL) | VAF 170/417 reads (41%) | called by mutect2, pindel, varscan2
- DLGAP3 | c.2000+1G>T p.X667_splice | Splice Site (SNP) | VAF 232/233 reads (100%) | called by muse, mutect2, varscan2
- DLGAP3 | c.2000G>T p.R667M | Missense Mutation (SNP) | VAF 234/235 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH17 | c.4309A>T p.M1437L | Missense Mutation (SNP) | VAF 619/620 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH6 | c.3205G>A p.A1069T | Missense Mutation (SNP) | VAF 218/445 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNAH6 | c.7180G>C p.D2394H | Missense Mutation (SNP) | VAF 70/331 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DNHD1 | c.8759A>T p.E2920V | Missense Mutation (SNP) | VAF 296/296 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DNTT | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 171/172 reads (99%) | called by muse, mutect2, varscan2
- DSEL | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- DSG1 | c.2984G>T p.G995V | Missense Mutation (SNP) | VAF 348/348 reads (100%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DZIP3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 103/164 reads (63%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1153A>T p.R385* | Nonsense Mutation (SNP) | VAF 280/448 reads (63%) | called by muse, mutect2, varscan2
- ENPEP | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 126/567 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- F2RL3 | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 488/491 reads (99%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAF2 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 381/619 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAT3 | c.1431T>A p.Y477* | Nonsense Mutation (SNP) | VAF 232/362 reads (64%) | called by muse, mutect2, varscan2
- FCRL4 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 309/795 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FH | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 208/291 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG2 | c.1407T>A p.H469Q | Missense Mutation (SNP) | VAF 347/832 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FRAS1 | c.11123A>G p.N3708S | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- FUT11 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 617/617 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GAS2L1 | c.1943C>G p.P648R | Missense Mutation (SNP) | VAF 202/640 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GBX2 | c.751C>G p.R251G | Missense Mutation (SNP) | VAF 205/652 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GC | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 107/337 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCG | c.311C>A p.T104N | Missense Mutation (SNP) | VAF 292/438 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GCNA | c.1556A>T p.D519V | Missense Mutation (SNP) | VAF 240/240 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- GDF3 | c.834G>C p.W278C | Missense Mutation (SNP) | VAF 300/593 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GORAB | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 196/374 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- GPR15 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 253/533 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR83 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 272/411 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPRIN1 | c.2256del p.E753Sfs*74 | Frame Shift Del (DEL) | VAF 236/765 reads (31%) | called by mutect2, pindel, varscan2
- GRIN2B | c.3479A>G p.D1160G | Missense Mutation (SNP) | VAF 176/757 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GRM3 | c.2520C>G p.H840Q | Missense Mutation (SNP) | VAF 133/407 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- GRM5 | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 153/422 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIPK1 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXC13 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 343/776 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR2A | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 80/212 reads (38%) | called by muse, mutect2, varscan2
- HTR2A | c.1350G>C p.K450N | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR3E | c.467T>C p.M156T (on ENST00000415389 / NM_001256613.1; = p.M171T on NM_182589.2) | Missense Mutation (SNP) | VAF 153/417 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IGHMBP2 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 168/249 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGKV2-28 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 82/270 reads (30%) | called by muse, mutect2, varscan2
- IGLV5-37 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 221/329 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IL22 | c.95C>G p.A32G | Missense Mutation (SNP) | VAF 228/492 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ITGA2 | c.2141G>T p.R714M | Missense Mutation (SNP) | VAF 110/204 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGAX | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 150/528 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1210 | c.2583C>G p.N861K | Missense Mutation (SNP) | VAF 293/294 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- KIR2DL4 | c.940A>T p.M314L (on ENST00000396284; = p.M240L on NM_001080770.2) | Missense Mutation (SNP) | VAF 120/413 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- KLF14 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 465/733 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KLHL24 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 135/362 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LARGE2 | c.492_492+14del p.X164_splice | Splice Site (DEL) | VAF 146/521 reads (28%) | called by mutect2, pindel, varscan2
- LGSN | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 99/269 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- LIPI | c.1179T>A p.Y393* | Nonsense Mutation (SNP) | VAF 101/272 reads (37%) | called by muse, varscan2
- LMNA | c.1600A>G p.T534A | Missense Mutation (SNP) | VAF 89/506 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LPCAT3 | c.408C>G p.N136K | Missense Mutation (SNP) | VAF 206/439 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- LRRC70 | c.901A>T p.N301Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MACF1 | c.19860G>T p.L6620F (on ENST00000372915; = p.L4665F on NM_012090.5) | Missense Mutation (SNP) | VAF 366/367 reads (100%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2770G>T p.V924F | Missense Mutation (SNP) | VAF 194/560 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP3K19 | c.1426C>A p.P476T | Missense Mutation (SNP) | VAF 141/418 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAP3K7 | c.909G>C p.Q303H | Missense Mutation (SNP) | VAF 156/248 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MAST4 | c.7291G>T p.A2431S (on ENST00000403625 / NM_001164664.2; = p.A2242S on NM_015183.3) | Missense Mutation (SNP) | VAF 194/451 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MCF2 | c.1700G>A p.C567Y | Missense Mutation (SNP) | VAF 160/160 reads (100%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MED12 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MFGE8 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 114/369 reads (31%) | called by muse, mutect2, varscan2
- MGAM2 | c.4361T>C p.V1454A | Missense Mutation (SNP) | VAF 150/246 reads (61%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MGAT5B | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 103/475 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MMP12 | c.83A>T p.N28I | Missense Mutation (SNP) | VAF 102/272 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MS4A4A | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 291/425 reads (68%) | SIFT tolerated (0.57); PolyPhen benign (0.096); called by muse, mutect2
- MUC17 | c.6035C>A p.T2012N | Missense Mutation (SNP) | VAF 114/414 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MXRA8 | c.533_547del p.R178_A182del | In Frame Del (DEL) | VAF 235/690 reads (34%) | called by mutect2, pindel, varscan2
- MYO1D | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MZF1 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 527/990 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- NBPF10 | c.2728C>G p.Q910E | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, varscan2
- NCS1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NELFCD | c.60C>A p.D20E (on ENST00000602795; = p.D2E on NM_198976.4) | Missense Mutation (SNP) | VAF 217/505 reads (43%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NF1 | c.7295A>G p.N2432S (on ENST00000358273 / NM_001042492.3; = p.N2411S on NM_000267.3) | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NOTCH1 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 160/327 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRP2 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 87/251 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NSUN2 | c.1084A>T p.T362S | Missense Mutation (SNP) | VAF 228/611 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NUF2 | c.1149A>T p.K383N | Missense Mutation (SNP) | VAF 206/349 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NUTM2F | c.751A>T p.M251L | Missense Mutation (SNP) | VAF 138/333 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, varscan2
- OCA2 | c.2402G>T p.G801V | Missense Mutation (SNP) | VAF 283/425 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLFML2A | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 374/374 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OOSP2 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 234/339 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OOSP4A | c.480-1G>T p.X160_splice | Splice Site (SNP) | VAF 82/284 reads (29%) | called by muse, mutect2, varscan2
- OR2T4 | c.828C>A p.H276Q | Missense Mutation (SNP) | VAF 479/739 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4N2 | c.325G>C p.G109R | Missense Mutation (SNP) | VAF 539/939 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- OR5AC2 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 91/474 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5AK2 | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- OR5F1 | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR5H15 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 153/343 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR7A17 | c.866T>G p.I289S | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR8H3 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 208/333 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 480/849 reads (57%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PASK | c.2905G>T p.V969L | Missense Mutation (SNP) | VAF 126/345 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PBXIP1 | c.666T>C p.T222= | Splice Region (SNP) | VAF 245/624 reads (39%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 232/736 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.196); called by muse, mutect2
- PCGF2 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 185/187 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PCYT1B | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PGR | c.2232dup p.D745* | Frame Shift Ins (INS) | VAF 91/289 reads (31%) | called by mutect2, pindel, varscan2
- PIK3C2B | c.2585G>T p.S862I | Missense Mutation (SNP) | VAF 414/656 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PLCB3 | c.3636C>G p.H1212Q | Missense Mutation (SNP) | VAF 274/858 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- PLD4 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 377/747 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- PLEC | c.2735A>T p.N912I (on ENST00000322810 / NM_201380.4; = p.N802I on NM_000445.5) | Missense Mutation (SNP) | VAF 401/588 reads (68%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PLEKHA2 | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 277/754 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLPPR3 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 189/189 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- POLQ | c.5183T>A p.I1728K | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- POM121L12 | c.717C>A p.S239R | Missense Mutation (SNP) | VAF 247/692 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PPFIA1 | c.2426G>T p.R809L | Missense Mutation (SNP) | VAF 139/495 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PPP1R12C | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 346/538 reads (64%) | called by mutect2, varscan2
- PPP4R3C | c.1140G>T p.R380S | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PREP | c.1246C>G p.P416A (on ENST00000369110; = p.P482A on NM_002726.5) | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRA | c.1246A>T p.T416S | Missense Mutation (SNP) | VAF 222/710 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PTPRD | c.4642C>A p.P1548T | Missense Mutation (SNP) | VAF 155/155 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- R3HDM1 | c.845C>G p.S282C | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- R3HDM1 | c.2595G>C p.K865N | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2
- RAB11FIP1 | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 150/967 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAG2 | c.1541T>G p.L514W | Missense Mutation (SNP) | VAF 105/584 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- RFXANK | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 368/368 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- RGPD1 | c.1307G>A p.W436* (on ENST00000409776; = p.W444* on NM_001024457.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 143/602 reads (24%) | called by muse, mutect2, varscan2
- RIT2 | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 183/183 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RNF145 | c.1691G>T p.W564L (on ENST00000424310 / NM_001199383.2; = p.W592L on NM_144726.2) | Missense Mutation (SNP) | VAF 246/390 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RP1 | c.3944G>T p.C1315F | Missense Mutation (SNP) | VAF 118/410 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- RSAD2 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 136/503 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RTN3 | c.2218C>G p.Q740E (on ENST00000377819 / NM_001265589.2; = p.Q721E on NM_201428.3) | Missense Mutation (SNP) | VAF 29/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- RYR1 | c.9191T>C p.V3064A | Missense Mutation (SNP) | VAF 190/722 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2
- SALL1 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 308/668 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- SAMD9 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 321/474 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SBSN | c.1084G>T p.G362W | Missense Mutation (SNP) | VAF 453/1068 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SBSN | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 582/1376 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCN1A | c.4074G>T p.W1358C (on ENST00000303395 / NM_001202435.3; = p.W1347C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/332 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCYL3 | c.1386A>G p.I462M | Missense Mutation (SNP) | VAF 107/549 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA3D | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 175/298 reads (59%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD1A | c.4094G>A p.G1365E | Missense Mutation (SNP) | VAF 472/732 reads (64%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- SETD2 | c.7462C>T p.P2488S | Missense Mutation (SNP) | VAF 251/251 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- SLC8A2 | c.2428T>A p.C810S | Missense Mutation (SNP) | VAF 165/661 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2
- SORBS2 | c.1166A>T p.N389I | Missense Mutation (SNP) | VAF 137/914 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SPAG17 | c.4882G>C p.E1628Q | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEF2 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 52/421 reads (12%) | called by muse, mutect2, varscan2
- SPIDR | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 111/305 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SRRM3 | c.1001C>A p.P334Q | Missense Mutation (SNP) | VAF 354/584 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SSR1 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- STXBP5 | c.2211G>T p.K737N | Missense Mutation (SNP) | VAF 147/242 reads (61%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SYNE1 | c.20644T>G p.S6882A (on ENST00000367255 / NM_182961.4; = p.S6811A on NM_033071.3) | Missense Mutation (SNP) | VAF 149/470 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYT4 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 229/230 reads (100%) | SIFT tolerated (0.53); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SZT2 | c.7796C>T p.S2599F (on ENST00000634258 / NM_001365999.1; = p.S2542F on NM_015284.4) | Missense Mutation (SNP) | VAF 393/397 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- TADA2A | c.1001_1015del p.Q334_R338del | In Frame Del (DEL) | VAF 84/221 reads (38%) | called by mutect2, pindel, varscan2
- TBCA | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- TDO2 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 342/417 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TDRD12 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 153/412 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TDRD15 | c.673G>C p.D225H | Missense Mutation (SNP) | VAF 155/332 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- TEX26 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 104/104 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TFR2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 382/564 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- THBS1 | c.1575G>C p.Q525H | Missense Mutation (SNP) | VAF 280/446 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- THSD7B | c.4119C>G p.C1373W (on ENST00000272643; = p.C1371W on NM_001316349.2) | Missense Mutation (SNP) | VAF 102/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132E | c.1997T>A p.L666Q (on ENST00000321639; = p.L756Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 291/291 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TMEM132E | c.1999G>A p.D667N (on ENST00000321639; = p.D757N on NM_001304438.2) | Missense Mutation (SNP) | VAF 294/294 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TMEM200A | c.1147G>T p.G383W | Missense Mutation (SNP) | VAF 123/353 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM41B | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMIGD1 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 241/242 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TNIK | c.1804G>T p.G602* | Nonsense Mutation (SNP) | VAF 75/261 reads (29%) | called by muse, mutect2, varscan2
- TNR | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 380/640 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TNS2 | c.2120T>G p.L707R (on ENST00000314250 / NM_170754.4; = p.L717R on NM_015319.2) | Missense Mutation (SNP) | VAF 399/879 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TOP2B | c.4649C>G p.S1550C (on ENST00000264331 / NM_001330700.2; = p.S1545C on NM_001068.3) | Missense Mutation (SNP) | VAF 103/193 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TP53 | c.618_619del p.D207* | Frame Shift Del (DEL) | VAF 292/292 reads (100%) | called by mutect2, pindel*, varscan2*
- TRAV19 | c.299C>A p.T100K | Missense Mutation (SNP) | VAF 393/650 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TRAV8-1 | c.160T>A p.W54R | Missense Mutation (SNP) | VAF 225/605 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAV8-6 | c.325T>A p.F109I | Missense Mutation (SNP) | VAF 169/403 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TRBV5-1 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 280/435 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- TRIM10 | c.837G>T p.R279S | Missense Mutation (SNP) | VAF 392/573 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIML1 | c.558C>A p.H186Q | Missense Mutation (SNP) | VAF 97/606 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- TRIML2 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 112/768 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRMT11 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRRAP | c.7985A>T p.Q2662L (on ENST00000359863 / NM_001244580.1; = p.Q2644L on NM_003496.3) | Missense Mutation (SNP) | VAF 153/479 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.54025T>C p.Y18009H (on ENST00000591111; = p.Y10585H on NM_003319.4) | Missense Mutation (SNP) | VAF 116/369 reads (31%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.10594C>A p.P3532T (on ENST00000591111; = p.P3486T on NM_003319.4) | Missense Mutation (SNP) | VAF 132/386 reads (34%) | called by muse, mutect2, varscan2
- TTYH2 | c.1135del p.A379Lfs*28 | Frame Shift Del (DEL) | VAF 219/529 reads (41%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 176/257 reads (68%) | SIFT tolerated (0.57); PolyPhen benign (0.181); called by muse, varscan2
- TUT4 | c.2180A>T p.K727M | Missense Mutation (SNP) | VAF 365/367 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- USP8 | c.1915G>C p.A639P | Missense Mutation (SNP) | VAF 132/191 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WNK1 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 198/455 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WNK3 | c.3508G>T p.D1170Y | Missense Mutation (SNP) | VAF 271/271 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- WSB2 | c.702G>C p.K234N | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZBED3 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 197/410 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2
- ZBTB4 | c.974A>G p.K325R | Missense Mutation (SNP) | VAF 337/337 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ZGRF1 | c.5765G>T p.G1922V | Missense Mutation (SNP) | VAF 126/196 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZGRF1 | c.5764G>T p.G1922* | Nonsense Mutation (SNP) | VAF 118/186 reads (63%) | called by muse, varscan2
- ZGRF1 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 390/539 reads (72%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZMAT4 | c.637T>A p.Y213N | Missense Mutation (SNP) | VAF 71/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF614 | c.899G>C p.R300P | Missense Mutation (SNP) | VAF 105/455 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ZNF664 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 130/376 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- ABCC12 | c.3066C>T p.L1022= | Silent (SNP) | VAF 218/218 reads (100%) | catalogued as COSV60912686; called by muse, mutect2, varscan2
- ALK | c.2505G>A p.P835= | Silent (SNP) | VAF 100/463 reads (22%) | catalogued as rs201700728; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMPH | c.1590C>T p.L530= | Silent (SNP) | VAF 98/349 reads (28%) | catalogued as rs201328417, COSV100340349, COSV57736176; called by muse, mutect2, varscan2
- ANKRD35 | c.1086C>G p.L362= | Silent (SNP) | VAF 194/1012 reads (19%) | called by muse, mutect2, varscan2
- ANKRD54 | c.303C>G p.L101= | Silent (SNP) | VAF 157/520 reads (30%) | catalogued as COSV53236953; called by muse, mutect2, varscan2
- ARMH1 | c.1233C>T p.S411= | Silent (SNP) | VAF 387/387 reads (100%) | called by muse, mutect2, varscan2
- ATF6B | c.273A>G p.P91= | Silent (SNP) | VAF 241/407 reads (59%) | catalogued as rs1008079847; called by muse, mutect2, varscan2
- BCL11B | c.567C>T p.R189= | Silent (SNP) | VAF 528/1047 reads (50%) | catalogued as rs922277828; called by muse, mutect2, varscan2
- BTNL3 | c.1335C>A p.I445= | Silent (SNP) | VAF 165/477 reads (35%) | called by muse, mutect2, varscan2
- CACNA1H | c.2034C>A p.G678= | Silent (SNP) | VAF 215/720 reads (30%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.1824C>A p.I608= | Silent (SNP) | VAF 256/570 reads (45%) | called by muse, mutect2, varscan2
- CAMTA1 | c.2190C>A p.A730= | Silent (SNP) | VAF 531/533 reads (100%) | called by muse, mutect2, varscan2
- CAND1 | c.2955G>C p.V985= | Silent (SNP) | VAF 83/401 reads (21%) | catalogued as COSV73389578; called by muse, mutect2, varscan2
- CAPN1 | c.1707C>T p.I569= | Silent (SNP) | VAF 142/395 reads (36%) | catalogued as rs1355860807; called by muse, mutect2, varscan2
- CCR9 | c.171C>T p.L57= (on ENST00000357632 / NM_031200.3; = p.L45= on NM_006641.4) | Silent (SNP) | VAF 263/264 reads (100%) | catalogued as rs537966588; called by muse, varscan2
- CD163L1 | c.3672T>G p.S1224= | Silent (SNP) | VAF 248/525 reads (47%) | called by muse, mutect2, varscan2
- CFAP161 | c.604T>C p.L202= | Silent (SNP) | VAF 212/333 reads (64%) | catalogued as rs984111620; called by muse, mutect2, varscan2
- CHRNA4 | c.1365C>A p.T455= | Silent (SNP) | VAF 357/823 reads (43%) | called by muse, mutect2, varscan2
- CLPS | c.276C>T p.I92= | Silent (SNP) | VAF 120/501 reads (24%) | catalogued as rs765091326; called by muse, mutect2, varscan2
- CLVS1 | c.240C>A p.L80= | Silent (SNP) | VAF 157/452 reads (35%) | catalogued as COSV100369725; called by muse, mutect2, varscan2
- CPD | c.3753C>G p.L1251= | Silent (SNP) | VAF 89/196 reads (45%) | catalogued as rs758360971, COSV56714100; called by muse, mutect2, varscan2
- CSN2 | c.324C>T p.V108= | Silent (SNP) | VAF 133/420 reads (32%) | called by muse, mutect2, varscan2
- CYP21A2 | c.1191G>A p.T397= | Silent (SNP) | VAF 141/934 reads (15%) | catalogued as rs775982691, COSV64484917; called by muse, mutect2, varscan2
- DCDC2C | c.483C>T p.S161= | Silent (SNP) | VAF 74/362 reads (20%) | catalogued as rs960819352; called by muse, mutect2, varscan2
- DENND2A | c.426C>A p.G142= | Silent (SNP) | VAF 404/596 reads (68%) | called by muse, mutect2, varscan2
- DHX36 | c.2508T>C p.C836= | Silent (SNP) | VAF 169/379 reads (45%) | called by muse, mutect2, varscan2
- DLGAP3 | c.432G>A p.G144= | Silent (SNP) | VAF 19/748 reads (3%) | called by muse, mutect2
- ESPN | c.414C>T p.G138= | Silent (SNP) | VAF 499/501 reads (100%) | catalogued as rs751089572, COSV100911531; called by muse, mutect2, varscan2
- ESRRB | c.1198C>A p.R400= | Silent (SNP) | VAF 364/817 reads (45%) | called by muse, mutect2
- EVI5L | c.1560C>T p.A520= | Silent (SNP) | VAF 168/540 reads (31%) | called by muse, mutect2, varscan2
- EXPH5 | c.5256G>T p.L1752= | Silent (SNP) | VAF 150/471 reads (32%) | called by muse, mutect2, varscan2
- F12 | c.1536G>C p.A512= | Silent (SNP) | VAF 152/429 reads (35%) | called by muse, mutect2, varscan2
- FAM221A | c.16T>C p.L6= | Silent (SNP) | VAF 239/239 reads (100%) | catalogued as rs775824411; called by muse, mutect2, varscan2
- FANCL | c.1127G>A p.*376= | Silent (SNP) | VAF 47/296 reads (16%) | called by muse, mutect2, varscan2
- FECH | c.330C>T p.F110= | Silent (SNP) | VAF 213/213 reads (100%) | called by muse, mutect2, varscan2
- FOXP2 | c.219G>A p.L73= | Silent (SNP) | VAF 224/372 reads (60%) | called by muse, mutect2, varscan2
- GAB4 | c.279C>A p.T93= | Silent (SNP) | VAF 116/398 reads (29%) | catalogued as COSV68754325; called by muse, mutect2, varscan2
- GBP1 | c.624G>A p.L208= | Silent (SNP) | VAF 170/170 reads (100%) | catalogued as COSV65084727; called by muse, mutect2, varscan2
- HCN4 | c.2595C>T p.F865= | Silent (SNP) | VAF 211/626 reads (34%) | catalogued as rs904535432, COSV56085395; called by muse, mutect2, varscan2
- HCN4 | c.2346G>T p.L782= | Silent (SNP) | VAF 187/652 reads (29%) | catalogued as rs939117369; called by muse, mutect2, varscan2
- HDAC7 | c.51C>T p.P17= (on ENST00000427332; = p.P56= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 522/1023 reads (51%) | called by muse, mutect2, varscan2
- HEATR5B | c.1002A>G p.V334= | Silent (SNP) | VAF 238/496 reads (48%) | called by muse, mutect2, varscan2
- HELT | c.378C>A p.A126= | Silent (SNP) | VAF 1181/1429 reads (83%) | catalogued as rs759268394; called by muse, mutect2, varscan2
- HPF1 | c.6C>G p.V2= | Silent (SNP) | VAF 121/991 reads (12%) | catalogued as rs765737535; called by muse, mutect2, varscan2
- HTR1A | c.504T>C p.S168= | Silent (SNP) | VAF 170/349 reads (49%) | called by muse, varscan2
- ICE2 | c.576C>T p.F192= | Silent (SNP) | VAF 77/217 reads (35%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.36T>G p.A12= | Silent (SNP) | VAF 201/450 reads (45%) | called by muse, mutect2, varscan2
- IL18R1 | c.375A>G p.V125= | Silent (SNP) | VAF 66/306 reads (22%) | called by muse, mutect2, varscan2
- KCNJ5 | c.414C>T p.S138= | Silent (SNP) | VAF 172/549 reads (31%) | catalogued as rs149219318; called by muse, mutect2, varscan2
- KIAA1549L | c.3243G>T p.R1081= (on ENST00000321505; = p.R1378= on NM_012194.3) | Silent (SNP) | VAF 308/651 reads (47%) | called by muse, mutect2, varscan2
- KIF21B | c.1986G>C p.T662= | Silent (SNP) | VAF 184/636 reads (29%) | catalogued as rs746573596, COSV100144524, COSV59758706; called by muse, mutect2, varscan2
- KLHL25 | c.339C>T p.N113= | Silent (SNP) | VAF 142/478 reads (30%) | catalogued as rs376662836; called by muse, varscan2
- KLHL30 | c.372C>T p.R124= | Silent (SNP) | VAF 193/614 reads (31%) | called by muse, mutect2, varscan2
- KMT2B | c.2917C>T p.L973= | Silent (SNP) | VAF 416/956 reads (44%) | catalogued as COSV99720340; called by muse, mutect2, varscan2
- KRTAP5-10 | c.135C>T p.P45= | Silent (SNP) | VAF 285/730 reads (39%) | catalogued as rs747606675; called by mutect2, varscan2
- MARCHF6 | c.2709A>T p.P903= | Silent (SNP) | VAF 175/517 reads (34%) | called by muse, mutect2, varscan2
- MARK2 | c.1716C>T p.A572= (on ENST00000402010 / NM_001039469.2; = p.A517= on NM_004954.5) | Silent (SNP) | VAF 397/646 reads (61%) | called by muse, mutect2, varscan2
- MON2 | c.5043A>G p.E1681= | Silent (SNP) | VAF 209/445 reads (47%) | called by muse, mutect2, varscan2
- MRGPRF | c.168G>A p.L56= | Silent (SNP) | VAF 198/571 reads (35%) | catalogued as rs779485318; called by muse, mutect2, varscan2
- MRPL45 | c.540C>G p.T180= | Silent (SNP) | VAF 311/311 reads (100%) | catalogued as rs774079302; called by muse, mutect2, varscan2
- MSGN1 | c.45G>A p.L15= | Silent (SNP) | VAF 215/499 reads (43%) | called by muse, mutect2, varscan2
- MUC4 | c.11610C>A p.A3870= | Silent (SNP) | VAF 196/608 reads (32%) | called by muse, mutect2, varscan2
- MUC4 | c.2049T>A p.P683= | Silent (SNP) | VAF 334/888 reads (38%) | called by muse, mutect2, varscan2
- MYLK3 | c.1302C>T p.D434= | Silent (SNP) | VAF 456/457 reads (100%) | catalogued as rs202183804, COSV67367379; called by muse, mutect2, varscan2
- MYO9A | c.189A>G p.L63= | Silent (SNP) | VAF 238/351 reads (68%) | called by muse, mutect2, varscan2
- NDUFA2 | c.225G>T p.T75= | Silent (SNP) | VAF 149/468 reads (32%) | catalogued as CD165997, COSV52799166; called by muse, mutect2, varscan2
- NEFM | c.1899A>T p.S633= | Silent (SNP) | VAF 193/195 reads (99%) | called by muse, mutect2, varscan2
- NINJ1 | c.234G>A p.V78= | Silent (SNP) | VAF 211/429 reads (49%) | called by muse, mutect2, varscan2
- NOD1 | c.1656G>T p.G552= | Silent (SNP) | VAF 329/330 reads (100%) | catalogued as rs998329569; called by muse, mutect2, varscan2
- NRXN3 | c.681A>G p.Q227= (on ENST00000557594 / NM_001272020.2; = p.Q859= on NM_004796.6) | Silent (SNP) | VAF 105/649 reads (16%) | catalogued as rs1376714407; called by muse, mutect2, varscan2
- NXPH3 | c.195C>T p.L65= | Silent (SNP) | VAF 969/970 reads (100%) | catalogued as COSV60872339; called by muse, mutect2, varscan2
- OR2AG2 | c.564C>A p.A188= | Silent (SNP) | VAF 244/244 reads (100%) | called by mutect2, varscan2
- OR52N1 | c.918C>T p.V306= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- OR6C1 | c.918T>C p.T306= | Silent (SNP) | VAF 146/311 reads (47%) | called by muse, mutect2, varscan2
- OTUD6A | c.327G>A p.Q109= | Silent (SNP) | VAF 449/449 reads (100%) | called by muse, mutect2, varscan2
- PADI4 | c.54G>T p.V18= | Silent (SNP) | VAF 368/370 reads (99%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1215T>C p.S405= | Silent (SNP) | VAF 581/953 reads (61%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1032C>A p.A344= | Silent (SNP) | VAF 307/465 reads (66%) | called by muse, mutect2, varscan2
- PLD5 | c.712T>C p.L238= (on ENST00000442594; = p.L176= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 225/338 reads (67%) | catalogued as COSV59169614; called by muse, mutect2, varscan2
- POPDC3 | c.360G>T p.G120= | Silent (SNP) | VAF 139/425 reads (33%) | catalogued as COSV54643652; called by muse, mutect2, varscan2
- POTEI | c.2880G>T p.A960= | Silent (SNP) | VAF 210/366 reads (57%) | called by muse, mutect2, varscan2
- PPCS | c.438A>G p.A146= | Silent (SNP) | VAF 495/495 reads (100%) | called by muse, mutect2, varscan2
- PPP2R5C | c.48C>G p.A16= | Silent (SNP) | VAF 165/636 reads (26%) | called by muse, mutect2, varscan2
- PSG1 | c.108C>T p.V36= | Silent (SNP) | VAF 106/479 reads (22%) | called by muse, mutect2, varscan2
- PTMA | c.30C>G p.S10= | Silent (SNP) | VAF 427/642 reads (67%) | called by muse, mutect2, varscan2
- PTPN3 | c.1542A>C p.T514= | Silent (SNP) | VAF 201/201 reads (100%) | called by muse, mutect2, varscan2
- QSER1 | c.3336G>T p.P1112= (on ENST00000399302; = p.P1241= on NM_001076786.3) | Silent (SNP) | VAF 202/430 reads (47%) | catalogued as COSV67901218; called by muse, mutect2, varscan2
- RGPD1 | c.4029T>C p.S1343= (on ENST00000409776; = p.S1351= on NM_001024457.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 305/653 reads (47%) | called by muse, mutect2, varscan2
- RNF114 | c.297C>T p.F99= | Silent (SNP) | VAF 134/258 reads (52%) | called by muse, mutect2, varscan2
- RPS27A | c.366T>A p.P122= | Silent (SNP) | VAF 304/609 reads (50%) | called by muse, mutect2, varscan2
- RYR1 | c.9192G>T p.V3064= | Silent (SNP) | VAF 191/726 reads (26%) | called by muse, mutect2
- RYR2 | c.14169C>A p.A4723= | Silent (SNP) | VAF 68/306 reads (22%) | called by muse, mutect2, varscan2
- SCAMP2 | c.498C>T p.N166= | Silent (SNP) | VAF 67/268 reads (25%) | catalogued as COSV99174002; called by muse, mutect2, varscan2
- SELP | c.1551G>A p.Q517= | Silent (SNP) | VAF 214/568 reads (38%) | called by muse, mutect2, varscan2
- SETD1A | c.4095G>T p.G1365= | Silent (SNP) | VAF 466/733 reads (64%) | catalogued as rs990642598; called by muse, varscan2
- SLAMF7 | c.294T>C p.N98= | Silent (SNP) | VAF 390/689 reads (57%) | called by muse, mutect2, varscan2
- SPATA5 | c.591G>C p.G197= | Silent (SNP) | VAF 113/482 reads (23%) | called by muse, mutect2, varscan2
- SPEF2 | c.2052T>C p.A684= | Silent (SNP) | VAF 51/417 reads (12%) | called by muse, mutect2, varscan2
- SRBD1 | c.1053C>T p.Y351= | Silent (SNP) | VAF 198/388 reads (51%) | called by muse, mutect2, varscan2
- SYNE3 | c.567G>A p.V189= | Silent (SNP) | VAF 295/753 reads (39%) | catalogued as COSV100515827; called by muse, mutect2, varscan2
- TBX3 | c.1818G>C p.T606= (on ENST00000257566 / NM_016569.4; = p.T586= on NM_005996.4) | Silent (SNP) | VAF 427/428 reads (100%) | catalogued as COSV57473897; called by muse, mutect2, varscan2
- TDRD6 | c.4491A>G p.S1497= | Silent (SNP) | VAF 143/223 reads (64%) | called by muse, mutect2, varscan2
- TENT2 | c.1116T>A p.A372= | Silent (SNP) | VAF 210/342 reads (61%) | catalogued as rs1412224504; called by muse, mutect2, varscan2
- TENT4A | c.1359C>T p.I453= | Silent (SNP) | VAF 92/497 reads (19%) | catalogued as rs1382692031; called by muse, mutect2, varscan2
- TIGD4 | c.117A>G p.K39= | Silent (SNP) | VAF 107/604 reads (18%) | called by muse, mutect2, varscan2
- TLCD3A | c.465G>A p.L155= | Silent (SNP) | VAF 240/240 reads (100%) | called by muse, varscan2
- TMEM132C | c.192C>A p.L64= | Silent (SNP) | VAF 319/319 reads (100%) | catalogued as rs1358063274; called by muse, mutect2, varscan2
- TMEM132D | c.1368C>G p.S456= | Silent (SNP) | VAF 320/320 reads (100%) | called by muse, mutect2, varscan2
- TMEM203 | c.234G>T p.R78= | Silent (SNP) | VAF 478/479 reads (100%) | called by muse, mutect2, varscan2
- TMEM275 | c.294G>T p.A98= | Silent (SNP) | VAF 292/304 reads (96%) | called by muse, mutect2, varscan2
- TNN | c.3373C>A p.R1125= | Silent (SNP) | VAF 153/451 reads (34%) | called by muse, mutect2, varscan2
- TNRC18 | c.4317C>T p.D1439= | Silent (SNP) | VAF 427/427 reads (100%) | catalogued as rs773309038; called by muse, mutect2, varscan2
- TRAF7 | c.1083A>G p.L361= | Silent (SNP) | VAF 228/341 reads (67%) | called by muse, mutect2, varscan2
- TRBV2 | c.120G>A p.L40= | Silent (SNP) | VAF 256/379 reads (68%) | called by muse, mutect2, varscan2
- TRGV9 | c.141A>G p.G47= | Silent (SNP) | VAF 113/326 reads (35%) | called by muse, mutect2, varscan2
- TSPYL2 | c.165A>G p.A55= | Silent (SNP) | VAF 635/636 reads (100%) | called by muse, mutect2, varscan2
- TST | c.405G>A p.L135= | Silent (SNP) | VAF 200/638 reads (31%) | called by muse, mutect2, varscan2
- UNC45B | c.2586G>C p.L862= | Silent (SNP) | VAF 268/268 reads (100%) | catalogued as rs778559923, COSV52096432; called by muse, mutect2, varscan2
- VIPAS39 | c.975A>G p.K325= | Silent (SNP) | VAF 391/691 reads (57%) | called by muse, mutect2, varscan2
- ZFAT | c.867C>T p.H289= | Silent (SNP) | VAF 198/556 reads (36%) | catalogued as rs1418002105; called by muse, mutect2, varscan2
- ZMYND15 | c.786A>G p.R262= | Silent (SNP) | VAF 323/323 reads (100%) | called by muse, mutect2, varscan2
- ZNF175 | c.2082C>T p.T694= | Silent (SNP) | VAF 74/352 reads (21%) | catalogued as COSV51796636, COSV99219466; called by muse, mutect2, varscan2
- ZNF382 | c.1245G>A p.K415= | Silent (SNP) | VAF 226/598 reads (38%) | called by muse, mutect2, varscan2
- ZNF521 | c.3540A>G p.P1180= | Silent (SNP) | VAF 92/360 reads (26%) | catalogued as rs1192312668; called by muse, mutect2, varscan2
- ZNF568 | c.402G>A p.A134= | Silent (SNP) | VAF 237/490 reads (48%) | catalogued as rs932866401; called by muse, mutect2, varscan2
- ZNF614 | c.900C>T p.R300= | Silent (SNP) | VAF 107/460 reads (23%) | called by muse, mutect2, varscan2
- ZNF710 | c.39C>G p.A13= | Silent (SNP) | VAF 146/426 reads (34%) | called by muse, mutect2, varscan2
- ZNF728 | c.1836A>G p.R612= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1437592776; called by muse, mutect2, varscan2
- ZNF804B | c.489G>A p.K163= | Silent (SNP) | VAF 110/347 reads (32%) | catalogued as rs1327759702; called by muse, mutect2, varscan2
- ZNF845 | c.1413T>C p.D471= | Silent (SNP) | VAF 106/392 reads (27%) | catalogued as COSV72004110; called by muse, mutect2, varscan2
- ZNF879 | c.711T>C p.C237= | Silent (SNP) | VAF 258/449 reads (57%) | catalogued as rs754545501; called by muse, mutect2, varscan2
- AC010655.3 | n.59_60del | RNA (DEL) | VAF 79/366 reads (22%) | called by mutect2, pindel, varscan2
- AC063924.1 | chr12:45439838 C>G | 5'Flank (SNP) | VAF 175/392 reads (45%) | called by muse, mutect2, varscan2
- ARIH2 | chr3:48918483 T>C | 5'Flank (SNP) | VAF 191/444 reads (43%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59915C>T | Intron (SNP) | VAF 102/341 reads (30%) | called by muse, mutect2, varscan2
- EPHA8 | c.1315+79C>T | Intron (SNP) | VAF 199/555 reads (36%) | catalogued as COSV99384383; called by muse, mutect2, varscan2
- FAM217A | c.-74C>A | 5'UTR (SNP) | VAF 365/574 reads (64%) | called by muse, mutect2, varscan2
- FHL2 | c.-124G>T | 5'UTR (SNP) | VAF 567/1114 reads (51%) | catalogued as rs914887435; called by muse, mutect2, varscan2
- FLVCR2 | c.670-16500A>C | Intron (SNP) | VAF 114/619 reads (18%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+19975del | Intron (DEL) | VAF 263/364 reads (72%) | called by mutect2, pindel, varscan2
- LBX2 | chr2:74502677 G>A | 5'Flank (SNP) | VAF 394/741 reads (53%) | catalogued as COSV52043618; called by muse, mutect2, varscan2
- MBNL1 | c.1016-699A>G | Intron (SNP) | VAF 240/553 reads (43%) | catalogued as rs778821940; called by muse, mutect2, varscan2
- PAX4 | c.145-64C>A | Intron (SNP) | VAF 338/503 reads (67%) | called by muse, mutect2, varscan2
- PDE4D | c.455+124678C>G | Intron (SNP) | VAF 120/216 reads (56%) | called by muse, mutect2, varscan2
- RAVER1 | c.1432-902C>T | Intron (SNP) | VAF 104/355 reads (29%) | called by muse, mutect2, varscan2
- RNASE4 | c.-1G>T | 5'UTR (SNP) | VAF 205/465 reads (44%) | called by muse, mutect2, varscan2
- RPGR | c.2520+481G>T | Intron (SNP) | VAF 291/292 reads (100%) | called by muse, mutect2, varscan2
- SORBS2 | c.-197-6006G>T | Intron (SNP) | VAF 75/507 reads (15%) | called by muse, mutect2, varscan2
- SPATA3 | c.-1C>G | 5'UTR (SNP) | VAF 122/367 reads (33%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532483 T>G | 5'Flank (SNP) | VAF 96/579 reads (17%) | catalogued as COSV55270322, COSV99742904, COSV99744253; called by muse, mutect2, varscan2
- SUMF2 | c.733+262G>T | Intron (SNP) | VAF 161/532 reads (30%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.1471+267A>C | Intron (SNP) | VAF 80/438 reads (18%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3528G>C | Intron (SNP) | VAF 271/810 reads (33%) | called by muse, mutect2, varscan2
- ZSCAN32 | chr16:3382865 C>G | 3'Flank (SNP) | VAF 100/273 reads (37%) | called by muse, mutect2, varscan2
